Somatic mutation profile of tumor specimen TCGA-HC-A9TH-01A (aliquot TCGA-HC-A9TH-01A-11D-A41K-08) from TCGA case TCGA-HC-A9TH, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 58.8 years (21,460 days).
Specimen TCGA-HC-A9TH-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 934704fe-5f1f-4e59-8399-74131ebfef50.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HC-A9TH-10A (Blood Derived Normal), aliquot TCGA-HC-A9TH-10A-01D-A41N-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3bc5fd03-def7-4dfb-93f9-eb03e38cd867

The open-access MAF lists 49 somatic variants for this specimen: 38 protein-altering or splice-affecting, 11 silent.
By variant classification: Missense Mutation 32, Silent 11, Frame Shift Del 2, Nonsense Mutation 2, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 14/49 reads (29%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRA3 | c.2706T>A p.S902R | Missense Mutation (SNP) | VAF 17/189 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as COSV99293106; called by muse, mutect2
- ARNTL2 | c.746C>A p.S249* | Nonsense Mutation (SNP) | VAF 10/39 reads (26%) | catalogued as rs866647983, COSV99667646; called by muse, mutect2, varscan2
- CPN1 | c.397G>A p.G133S | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775743949, COSV100962584; called by muse, mutect2, varscan2
- CTRL | c.724C>T p.R242C | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.849); catalogued as rs200739617, COSV52123365; called by muse, mutect2, varscan2
- EP400 | c.7183C>A p.P2395T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100200848; called by muse, mutect2, varscan2
- ERBB4 | c.2620G>A p.E874K | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.994); catalogued as COSV100724644, COSV100728622, COSV61505389; called by muse, mutect2, varscan2
- FMN2 | c.2867C>T p.P956L | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.393); catalogued as rs752237802, COSV60416576; called by muse, mutect2, varscan2
- GRIN2B | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as rs752720799, COSV74206604; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GSN | c.2181T>A p.A727= | Splice Region (SNP) | VAF 16/52 reads (31%) | catalogued as COSV100375992; called by muse, mutect2, varscan2
- HECTD1 | c.6794C>G p.P2265R | Missense Mutation (SNP) | VAF 29/107 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101237336; called by muse, mutect2, varscan2
- IGSF10 | c.1304C>A p.S435Y | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as COSV99177336; called by muse, mutect2, varscan2
- INSRR | c.3466G>A p.V1156M | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779745536, COSV63871708; called by muse, mutect2, varscan2
- KDM2B | c.2234G>A p.G745D | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100997331; called by muse, mutect2
- KDR | c.1712G>A p.C571Y | Missense Mutation (SNP) | VAF 14/53 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99817162; called by muse, mutect2, varscan2
- LCT | c.2458G>A p.V820I | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs868496020, COSV51544740; called by muse, mutect2
- LRRC15 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.817); catalogued as rs530171790, COSV61651587; called by muse, mutect2, varscan2
- MUC2 | c.3122C>T p.P1041L | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.178); catalogued as rs762018613; called by muse, mutect2, varscan2
- NAA25 | c.460A>T p.M154L | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV99927459; called by muse, mutect2, varscan2
- NTF3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as rs1252054668, COSV100451084; called by muse, mutect2, varscan2
- PDCD2 | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV99388421; called by muse, mutect2
- PDGFRA | c.1783C>T p.L595F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99956165; called by muse, mutect2, varscan2
- SAMD7 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV100156840; called by muse, mutect2
- SARDH | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV100060593; called by muse, mutect2, varscan2
- SARDH | c.364G>T p.E122* | Nonsense Mutation (SNP) | VAF 9/83 reads (11%) | catalogued as COSV100060601; called by muse, mutect2, varscan2
- SFRP2 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 15/34 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99923235; called by muse, mutect2, varscan2
- SHANK1 | c.6220C>T p.R2074C | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs549670535, COSV53252620, COSV53263287; called by muse, mutect2, varscan2
- SLC5A11 | c.398G>A p.R133Q | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.48); PolyPhen benign (0.009); catalogued as rs746908912; called by muse, varscan2
- TADA2B | c.878G>A p.R293Q | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.866); catalogued as rs746850955, COSV99380591; called by muse, mutect2, varscan2
- TLR1 | c.2075A>C p.K692T | Missense Mutation (SNP) | VAF 18/184 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100458405, COSV58304414; called by muse, mutect2
- TMEM132D | c.2132G>T p.C711F | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1478143056, COSV101242679; called by muse, mutect2, varscan2
- TOR2A | c.937G>A p.V313M | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs559979121, COSV100262819; called by muse, mutect2, varscan2
- TRAPPC10 | c.642G>C p.E214D | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.16); PolyPhen benign (0.166); catalogued as COSV99378381; called by muse, mutect2, varscan2
- TRPM4 | c.1874-1G>C p.X625_splice | Splice Site (SNP) | VAF 48/195 reads (25%) | catalogued as COSV99419423; called by muse, mutect2, varscan2
- UCMA | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 46/119 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.067); catalogued as rs377345564; called by muse, mutect2, varscan2
- XIRP2 | c.6733C>A p.P2245T (on ENST00000628543; = p.P2420T on NM_152381.6) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen probably damaging (0.997); catalogued as COSV54711056, COSV99740821; called by muse, mutect2, varscan2
- YTHDC1 | c.183del p.K61Nfs*14 | Frame Shift Del (DEL) | VAF 16/55 reads (29%) | catalogued as COSV100704706; called by mutect2, pindel, varscan2
- CASZ1 | c.632del p.A211Gfs*96 | Frame Shift Del (DEL) | VAF 5/36 reads (14%) | called by mutect2, pindel, varscan2
- CTBS | c.849C>T p.D283= | Silent (SNP) | VAF 29/59 reads (49%) | catalogued as rs367692581; called by muse, mutect2, varscan2
- EPHB2 | c.366G>T p.S122= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs747882481, COSV101006870, COSV65863930; called by muse, mutect2, varscan2
- FKBP14 | c.615A>G p.T205= | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as rs577454244, COSV99767080; called by muse, mutect2, varscan2
- KCNV2 | c.1257C>T p.A419= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV101172550; called by muse, mutect2, varscan2
- KLK3 | c.474C>G p.G158= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as COSV100385965; called by muse, mutect2, varscan2
- KRTAP10-9 | c.117G>A p.P39= | Silent (SNP) | VAF 14/61 reads (23%) | catalogued as rs368541625; called by muse, mutect2, varscan2
- PCDHA4 | c.1461C>T p.N487= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs139246893; called by muse, mutect2, varscan2
- PCDHA4 | c.1671C>T p.D557= | Silent (SNP) | VAF 29/65 reads (45%) | catalogued as rs1451689285, COSV63545662; called by muse, mutect2, varscan2
- RUNX3 | c.436C>A p.R146= | Silent (SNP) | VAF 25/69 reads (36%) | catalogued as rs1330670662, COSV100136772; called by muse, mutect2, varscan2
- SLC9A8 | c.753C>G p.V251= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as rs367591345; called by muse, mutect2, varscan2
- TLR4 | c.748C>T p.L250= (on ENST00000355622 / NM_138554.5; = p.L210= on NM_003266.4) | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as COSV100790628; called by muse, mutect2, varscan2
